TARGET case TARGET-30-PAJYLA — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Peripheral nerves and autonomic nervous system. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/5639c09d-56d3-5519-b398-c241c88e79ef

Demographics
Sex at birth: male; Vital status: Dead.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Age at diagnosis: 1.5 years (562 days); Year of diagnosis: 1989; Days to last follow up: 368 days (1.0 years); INSS stage: Stage 4.

Biospecimens (1 sample)
- Sample TARGET-30-PAJYLA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
